Somatic mutation profile of tumor specimen TCGA-55-A494-01A (aliquot TCGA-55-A494-01A-11D-A24P-08) from TCGA case TCGA-55-A494, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.7 years (22,540 days).
Specimen TCGA-55-A494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cab1757b-8756-4c73-81d9-8d3d390cbeda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A494-10A (Blood Derived Normal), aliquot TCGA-55-A494-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14e8ffd2-f531-4120-87f8-82f33d934692

The open-access MAF lists 255 somatic variants for this specimen: 195 protein-altering or splice-affecting, 51 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 51, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 4, Intron 3, RNA 3, Splice Region 2, 3'Flank 2, Nonstop Mutation 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/33 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99191024; called by muse, mutect2, varscan2
- ABCB1 | c.2660A>T p.K887M | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714228; called by muse, mutect2, varscan2
- ACTRT1 | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 108/562 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100947656, COSV100947750; called by muse, mutect2, varscan2
- AFF2 | c.3383C>A p.S1128Y | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666035; called by muse, mutect2, varscan2
- AFF3 | c.3332G>A p.G1111E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100419989; called by muse, mutect2, varscan2
- AIFM1 | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 178/409 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99781429; called by muse, mutect2, varscan2
- AMBRA1 | c.1165G>C p.G389R (on ENST00000458649 / NM_001367468.1; = p.G299R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs925840392; called by muse, mutect2, varscan2
- AMPD1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752158310, COSV62415035; called by muse, mutect2, varscan2
- ANK2 | c.8687C>A p.S2896Y | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100002823, COSV100003958; called by muse, mutect2, varscan2
- ARAP3 | c.3872+1G>A p.X1291_splice | Splice Site (SNP) | VAF 29/156 reads (19%) | catalogued as rs1318644389, COSV99500236; called by muse, mutect2, varscan2
- ARSH | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV101139981; called by muse, mutect2, varscan2
- BCL11A | c.1202C>T p.T401M (on ENST00000335712 / NM_001365609.1; = p.T435M on NM_018014.4) | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs768965403, COSV59636434; called by muse, mutect2, varscan2
- BCORL1 | c.3974G>A p.G1325D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV99500797; called by muse, mutect2, varscan2
- BEND2 | c.1382G>T p.S461I | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV101192202; called by muse, mutect2, varscan2
- BNC1 | c.1477C>A p.R493S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100597453; called by muse, mutect2, varscan2
- BNC1 | c.1230C>A p.N410K | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747870739, COSV100597456; called by muse, mutect2, varscan2
- BRINP3 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100819394; called by muse, mutect2, varscan2
- C12orf71 | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV101460556; called by muse, mutect2, varscan2
- C1GALT1C1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV100485649; called by muse, mutect2, varscan2
- CAGE1 | c.1883T>A p.L628H (on ENST00000512086; = p.L492H on NM_205864.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99700102; called by muse, mutect2, varscan2
- CBLL2 | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 117/320 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100081730; called by muse, mutect2, varscan2
- CCDC73 | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100068276; called by muse, mutect2, varscan2
- CCDC74A | c.466A>C p.S156R | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99723914; called by muse, mutect2, varscan2
- CCNA2 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs761870224, COSV99697143; called by muse, mutect2
- CCNB3 | c.1754C>A p.S585* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV52070700, COSV99329791; called by muse, mutect2, varscan2
- CDH16 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs149161540; called by muse, mutect2, varscan2
- CDH18 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99937993; called by muse, mutect2, varscan2
- CDHR2 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV99992149; called by muse, mutect2, varscan2
- CIAO2A | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99976401; called by muse, mutect2, varscan2
- CMTM5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.682); catalogued as rs756622705, COSV100198194; called by muse, mutect2, varscan2
- COL7A1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100097581; called by muse, mutect2, varscan2
- COL9A1 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295485, COSV57878956; called by muse, mutect2, varscan2
- CRYGD | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99965379; called by muse, mutect2, varscan2
- CUX2 | c.637+1G>T p.X213_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99920659; called by muse, mutect2, varscan2
- DGKI | c.759G>C p.W253C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937062; called by muse, mutect2, varscan2
- DGKI | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937064; called by muse, mutect2, varscan2
- DLX2 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as COSV99308586, COSV99308667; called by muse, mutect2
- DNAJC13 | c.363G>T p.W121C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99608020; called by muse, mutect2, varscan2
- E2F4 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100681892; called by muse, mutect2, varscan2
- EGFLAM | c.2351C>A p.A784E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100380738, COSV59297476; called by muse, mutect2, varscan2
- EIF5A2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858831; called by muse, mutect2, varscan2
- EPHA5 | c.2396G>T p.R799I | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99901032; called by muse, mutect2, varscan2
- ESPNL | c.2732G>T p.G911V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547926; called by muse, mutect2, varscan2
- F8 | c.268C>T p.L90= | Splice Region (SNP) | VAF 98/274 reads (36%) | catalogued as COSV100811892, COSV64276715; called by muse, mutect2, varscan2
- FCGR3B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 69/143 reads (48%) | catalogued as COSV99670744; called by muse, mutect2, varscan2
- FGFR4 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99450816; called by muse, mutect2, varscan2
- FRMPD2 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs376780885; called by muse, mutect2
- GASK1B | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV99648100; called by muse, mutect2, varscan2
- GATD1 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100168768; called by muse, mutect2, varscan2
- GDPD2 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100978697; called by muse, mutect2, varscan2
- GJB7 | c.671G>C p.*224Sext*8 | Nonstop Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99738712; called by muse, varscan2
- GJB7 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51529310, COSV99738732, COSV99738806; called by muse, mutect2, varscan2
- GNAS | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55670523; called by muse, mutect2, varscan2
- GPA33 | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 54/170 reads (32%) | catalogued as COSV100901259; called by muse, mutect2, varscan2
- GRID2 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946187; called by muse, mutect2, varscan2
- GRIK4 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV101483738; called by muse, mutect2, varscan2
- GRM3 | c.2032C>A p.Q678K | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.2); catalogued as COSV100862854; called by muse, mutect2, varscan2
- H4C4 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100534495; called by muse, mutect2, varscan2
- HDAC6 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100491231; called by muse, mutect2, varscan2
- HECTD4 | c.4641G>C p.Q1547H | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV101108350; called by muse, mutect2, varscan2
- HEPH | c.1574C>G p.A525G (on ENST00000343002; = p.A258G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100295633, COSV57964859; called by muse, mutect2, varscan2
- HIVEP1 | c.4156A>T p.K1386* | Nonsense Mutation (SNP) | VAF 45/187 reads (24%) | catalogued as COSV101045687, COSV65100172; called by muse, mutect2, varscan2
- HMCN1 | c.6701G>T p.G2234V | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99635047; called by muse, mutect2, varscan2
- HNRNPH2 | c.738T>A p.Y246* | Nonsense Mutation (SNP) | VAF 72/161 reads (45%) | catalogued as COSV99516583; called by muse, mutect2, varscan2
- HOXA3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs770556616, COSV100415673; called by muse, mutect2, varscan2
- IFI44 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV100877417; called by muse, mutect2, varscan2
- KCND2 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100478360; called by muse, mutect2, varscan2
- KCNJ3 | c.919+1G>C p.X307_splice | Splice Site (SNP) | VAF 43/72 reads (60%) | catalogued as COSV99716403; called by muse, mutect2, varscan2
- KDR | c.3419T>A p.L1140Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99818543; called by muse, mutect2, varscan2
- KIAA1549L | c.4642G>A p.D1548N (on ENST00000321505; = p.D1845N on NM_012194.3) | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs529048568, COSV100382304; called by muse, mutect2, varscan2
- KIF18A | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs768557714, COSV54187175; called by muse, mutect2, varscan2
- KIF6 | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV54698156, COSV99760522; called by muse, mutect2, varscan2
- KLHL34 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs771035738, COSV101069992; called by muse, mutect2, varscan2
- KRBA1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.579); catalogued as COSV55444512; called by muse, mutect2, varscan2
- KRT222 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs767766381, COSV101229483; called by muse, mutect2, varscan2
- LBX1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929972; called by muse, mutect2, varscan2
- LIPG | c.764A>T p.N255I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.765); catalogued as COSV99724712; called by muse, mutect2
- LONRF3 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV100504656; called by muse, mutect2
- LRP1B | c.10267G>T p.G3423C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101260356, COSV67212758; called by muse, mutect2, varscan2
- LRRC4B | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100976033; called by muse, varscan2
- MAGEB6 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV66872753; called by muse, mutect2, varscan2
- MAGEE2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs757100041, COSV64897913; called by muse, mutect2, varscan2
- MAGI3 | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | catalogued as COSV100290319; called by muse, mutect2, varscan2
- MBIP | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs1191234136, COSV100576827; called by muse, mutect2
- MED12 | c.2303G>C p.R768P | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100377867, COSV100379778, COSV61345467; called by muse, mutect2, varscan2
- MFGE8 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427835660, COSV51557272; called by muse, mutect2, varscan2
- MKI67 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100896956; called by muse, mutect2, varscan2
- MRE11 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60578785; called by muse, mutect2, varscan2
- MTBP | c.2679G>T p.V893= | Splice Region (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100012540; called by muse, mutect2, varscan2
- MUC16 | c.3576G>T p.M1192I | Missense Mutation (SNP) | VAF 100/122 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101201423; called by muse, mutect2, varscan2
- MUC17 | c.8525C>A p.T2842N | Missense Mutation (SNP) | VAF 422/839 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV100074932; called by muse, mutect2, varscan2
- MYH3 | c.2891A>T p.K964M | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99878813; called by muse, mutect2, varscan2
- MYO3A | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99781403; called by muse, mutect2, varscan2
- MYOF | c.5828A>T p.Q1943L | Missense Mutation (SNP) | VAF 244/427 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100826096; called by muse, mutect2, varscan2
- NLGN3 | c.1760G>A p.R587H (on ENST00000358741 / NM_181303.2; = p.R567H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170891086, COSV100705037; called by muse, mutect2, varscan2
- NLRC5 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 56/111 reads (50%) | catalogued as rs775880379, COSV99348150; called by muse, mutect2, varscan2
- NLRP13 | c.1780A>T p.K594* | Nonsense Mutation (SNP) | VAF 69/109 reads (63%) | catalogued as COSV100738496; called by muse, mutect2, varscan2
- NOTCH4 | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100900977, COSV66685402; called by muse, mutect2, varscan2
- NPAP1 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as COSV100276125; called by muse, mutect2, varscan2
- NRXN3 | c.2682C>A p.H894Q (on ENST00000335750 / NM_001330195.2; = p.H521Q on NM_004796.6) | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100208550; called by muse, mutect2, varscan2
- OAF | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs777680684, COSV100202911, COSV100202999; called by muse, mutect2, varscan2
- OBSCN | c.10899G>T p.R3633S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as COSV52788044, COSV99483842; called by muse, mutect2, varscan2
- OR11H12 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101612527; called by mutect2, varscan2
- OR1C1 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV101376277; called by muse, mutect2, varscan2
- OR2A14 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 127/366 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101376493; called by muse, mutect2, varscan2
- OR4A16 | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100125390; called by muse, mutect2, varscan2
- OR4C15 | c.602C>A p.A201D (on ENST00000314644; = p.A147D on NM_001001920.2) | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100115561, COSV100116073, COSV58951716; called by muse, mutect2, varscan2
- OR4K13 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199734457; called by muse, mutect2, varscan2
- OR52R1 | c.925G>T p.G309* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100617794; called by muse, mutect2, varscan2
- OR52R1 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100617795; called by muse, mutect2, varscan2
- OR5L1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100450153, COSV100450238; called by muse, mutect2, varscan2
- OR5W2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV60618837; called by muse, mutect2, varscan2
- PANX3 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV52511465; called by muse, mutect2
- PCOLCE2 | c.441C>G p.N147K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV56001253, COSV99930916; called by muse, mutect2, varscan2
- PDE1B | c.1435G>T p.V479F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV99226514; called by muse, mutect2, varscan2
- PLAT | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 391/518 reads (75%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV99535050; called by muse, mutect2, varscan2
- PNPLA4 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV101124423; called by muse, mutect2, varscan2
- PPFIBP1 | c.1876C>T p.R626* (on ENST00000318304 / NM_177444.3; = p.R620* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 32/177 reads (18%) | catalogued as rs926183414, COSV57290416; called by muse, mutect2, varscan2
- PPP1R12A | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1344999292, COSV99700800; called by muse, mutect2, varscan2
- PRDM9 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV99691174; called by muse, varscan2
- PRSS53 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs757652726, COSV99762639; called by muse, mutect2, varscan2
- PTPRA | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99400569; called by muse, mutect2, varscan2
- PTPRO | c.903C>A p.D301E | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV99841619; called by muse, mutect2, varscan2
- RAB40A | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as COSV100420915, COSV100421016, COSV58491659; called by muse, mutect2, varscan2
- REG1B | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100521514; called by muse, mutect2, varscan2
- RNF128 | c.615C>A p.H205Q (on ENST00000255499 / NM_194463.2; = p.H179Q on NM_024539.3) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV99718487; called by muse, mutect2, varscan2
- ROBO2 | c.3101G>T p.G1034V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV100169708; called by muse, mutect2, varscan2
- RTL3 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); catalogued as COSV100330067; called by muse, mutect2, varscan2
- SATL1 | c.283A>C p.S95R (on ENST00000395409; = p.S282R on NM_001012980.2) | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100261096; called by muse, mutect2, varscan2
- SDC4 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV101023564; called by muse, mutect2, varscan2
- SERPINB11 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV101236323; called by muse, mutect2, varscan2
- SERPINB4 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV100345972; called by muse, mutect2, varscan2
- SERPINB5 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237694; called by muse, mutect2, varscan2
- SHKBP1 | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99399363; called by muse, mutect2, varscan2
- SLC16A9 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs948084691, COSV101264472; called by muse, mutect2, varscan2
- SLC35B3 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs866348642, COSV100217409; called by muse, mutect2, varscan2
- SLC44A5 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100902599; called by muse, mutect2, varscan2
- SLC44A5 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100902601, COSV63763805; called by muse, mutect2, varscan2
- SLC6A5 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100117120; called by muse, mutect2, varscan2
- SLCO3A1 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as COSV100575889; called by muse, mutect2, varscan2
- SMC1A | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV59129247; called by muse, mutect2, varscan2
- SMO | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99977063; called by muse, mutect2, varscan2
- SNTG1 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99385872; called by muse, mutect2
- SPTB | c.5704A>C p.T1902P | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101072394; called by muse, mutect2, varscan2
- SPTB | c.3028C>G p.R1010G | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV101072395; called by muse, mutect2, varscan2
- SRRM4 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99939350; called by muse, mutect2
- SSH3 | c.233A>G p.Q78R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV100354782; called by muse, mutect2, varscan2
- SUSD3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100968916, COSV64937021; called by muse, mutect2, varscan2
- TAF1C | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.862); catalogued as COSV100499780; called by muse, mutect2, varscan2
- TAS2R19 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs750823944, COSV101115545; called by muse, varscan2
- TEX10 | c.2690G>A p.G897E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99318202; called by muse, mutect2, varscan2
- THEMIS | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 87/125 reads (70%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs576573692, COSV100965546; called by muse, mutect2, varscan2
- THSD7B | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 109/157 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0.044); catalogued as COSV55656988, COSV55729313; called by muse, mutect2, varscan2
- TICRR | c.5305G>C p.G1769R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99179671; called by muse, mutect2, varscan2
- TINAGL1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs768382785, COSV99593085; called by muse, mutect2, varscan2
- TLK1 | c.2008G>A p.G670S | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100688767; called by muse, mutect2, varscan2
- TMED2 | c.319A>T p.M107L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV51630378; called by muse, mutect2, varscan2
- TMEM109 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV99137040; called by muse, mutect2, varscan2
- TMEM211 | c.266C>A p.S89Y (on ENST00000423535; = p.S18Y on NM_001001663.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV101236046; called by muse, varscan2
- TMPRSS11B | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100219509, COSV60293480; called by muse, mutect2, varscan2
- TMTC4 | c.1848G>C p.E616D (on ENST00000376234 / NM_001350577.2; = p.E635D on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100168874; called by muse, mutect2, varscan2
- TPD52L2 | c.590A>T p.D197V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99410865; called by muse, mutect2, varscan2
- TPTE2 | c.358C>A p.L120I (on ENST00000400230 / NM_199254.2; = p.L83I on NM_130785.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV99690895; called by muse, mutect2, varscan2
- TREML4 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV100422989; called by muse, mutect2
- TRIM60 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV100594118; called by muse, mutect2, varscan2
- TSHZ3 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53677292, COSV99553158; called by muse, mutect2, varscan2
- TSKS | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99883666; called by muse, mutect2, varscan2
- TSPAN18 | c.383A>C p.N128T | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100418911; called by muse, mutect2, varscan2
- TTN | c.93323C>A p.A31108D (on ENST00000591111; = p.A23684D on NM_003319.4) | Missense Mutation (SNP) | VAF 62/96 reads (65%) | PolyPhen probably damaging (0.999); catalogued as COSV100628132; called by muse, mutect2, varscan2
- TTN | c.75537G>T p.Q25179H (on ENST00000591111; = p.Q17755H on NM_003319.4) | Missense Mutation (SNP) | VAF 45/233 reads (19%) | PolyPhen possibly damaging (0.879); catalogued as COSV100628133, COSV100634861; called by muse, mutect2, varscan2
- UNC79 | c.7052C>A p.P2351H (on ENST00000393151 / NM_001346218.2; = p.P2174H on NM_020818.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV99829737; called by muse, mutect2, varscan2
- VIT | c.1627C>A p.Q543K (on ENST00000389975 / NM_001177969.1; = p.Q558K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374139011, COSV101007741; called by muse, mutect2, varscan2
- VWA3B | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101346152; called by muse, mutect2, varscan2
- WFDC5 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100332197; called by muse, mutect2, varscan2
- ZBTB33 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV100434316; called by muse, mutect2, varscan2
- ZNF180 | c.1310A>T p.Y437F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99660063; called by muse, mutect2, varscan2
- ZNF221 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99240935; called by muse, mutect2, varscan2
- ZNF585B | c.2174A>C p.K725T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100459629; called by muse, mutect2, varscan2
- ZNF648 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs771153275, COSV60571907; called by muse, mutect2, varscan2
- ZPLD1 | c.463T>A p.C155S (on ENST00000466937 / NM_001329788.1; = p.C171S on NM_175056.2) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100083531; called by muse, mutect2, varscan2
- ZXDC | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100306627; called by muse, mutect2
- AKAP17A | c.955_956del p.E319Rfs*14 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- ARHGEF12 | c.4173_4193del p.N1392_G1398del | In Frame Del (DEL) | VAF 19/134 reads (14%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 148/253 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MRC1 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 87/309 reads (28%) | called by muse, mutect2, varscan2
- NOVA2 | c.613del p.Q205Rfs*191 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- PHKA2 | c.1793+1del p.X598_splice | Splice Site (DEL) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- PRKAB1 | c.260dup p.G88Rfs*15 | Frame Shift Ins (INS) | VAF 39/213 reads (18%) | called by mutect2, pindel, varscan2
- SMC3 | c.2954del p.K985Rfs*7 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SPATA31A1 | c.2715G>T p.W905C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); called by mutect2, varscan2
- TBC1D20 | c.1128_1135del p.V377Wfs*17 | Frame Shift Del (DEL) | VAF 74/213 reads (35%) | called by mutect2, pindel, varscan2
- TPTE | c.1162C>G p.P388A (on ENST00000618007 / NM_199261.4; = p.P370A on NM_199259.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- XAGE2 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ABLIM1 | c.783C>T p.T261= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs144146814; called by muse, mutect2, varscan2
- AP2A2 | c.2286C>T p.D762= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs752018943, COSV100173305; called by muse, mutect2, varscan2
- B4GALNT2 | c.933C>T p.Y311= | Silent (SNP) | VAF 73/368 reads (20%) | catalogued as rs138230946; called by muse, mutect2, varscan2
- CD300E | c.585G>A p.V195= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV60791479; called by muse, mutect2, varscan2
- CDH12 | c.2028G>T p.G676= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV66403543; called by muse, mutect2, varscan2
- CDH18 | c.1161C>T p.S387= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV99937996; called by muse, mutect2, varscan2
- CFC1 | c.183G>C p.V61= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs765945822, COSV99383518; called by muse, mutect2, varscan2
- CHD8 | c.4851A>G p.Q1617= (on ENST00000646647 / NM_001170629.2; = p.Q1338= on NM_020920.4) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs764738563, COSV100783865; called by muse, mutect2, varscan2
- EEF2 | c.93C>T p.G31= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV100500973, COSV58580484; called by muse, mutect2, varscan2
- FBXL7 | c.1269G>T p.L423= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100310734, COSV61650386; called by muse, mutect2, varscan2
- FLG | c.11397C>A p.A3799= | Silent (SNP) | VAF 361/1028 reads (35%) | catalogued as COSV100912094; called by muse, mutect2, varscan2
- GABRR3 | c.877C>A p.R293= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101512350; called by muse, mutect2, varscan2
- GJB7 | c.594G>A p.L198= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99738718; called by muse, varscan2
- H3C4 | c.342C>T p.H114= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs1270187746, COSV100587268; called by muse, mutect2, varscan2
- KALRN | c.8943G>T p.R2981= (on ENST00000360013 / NM_001024660.4; = p.R1284= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99362880; called by muse, mutect2, varscan2
- KCNS2 | c.108G>A p.L36= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV99751427; called by muse, mutect2
- KCNT2 | c.3075C>A p.G1025= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV99656524; called by muse, mutect2, varscan2
- KIF16B | c.159C>G p.T53= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV100734879; called by muse, mutect2, varscan2
- KIF18A | c.1467T>C p.T489= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1168074770, COSV99589078; called by muse, mutect2, varscan2
- KRT18 | c.1041A>C p.S347= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101184119; called by muse, mutect2
- LILRB1 | c.1216A>C p.R406= (on ENST00000427581; = p.R370= on NM_006669.6) | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV100207833; called by muse, mutect2, varscan2
- LRP1B | c.1575C>T p.L525= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV67275027; called by muse, mutect2, varscan2
- MAGEA4 | c.252C>A p.P84= | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as COSV99367696; called by muse, mutect2, varscan2
- MAGEB1 | c.783C>T p.P261= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as COSV100974950, COSV100975092; called by muse, mutect2, varscan2
- MAGEE1 | c.1005C>A p.T335= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100819386; called by muse, mutect2, varscan2
- MAPT | c.681C>T p.G227= (on ENST00000262410 / NM_001377265.1; = p.G152= on NM_016835.4) | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99291259; called by muse, mutect2
- MYH4 | c.3969A>G p.L1323= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as COSV99702141; called by muse, mutect2, varscan2
- MYO19 | c.390C>T p.V130= | Silent (SNP) | VAF 107/278 reads (38%) | called by muse, mutect2, varscan2
- MYRIP | c.1080T>C p.D360= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as COSV100219949; called by muse, mutect2, varscan2
- OR2A14 | c.666C>A p.A222= | Silent (SNP) | VAF 126/362 reads (35%) | catalogued as COSV101376494, COSV68718477, COSV68718683; called by muse, mutect2, varscan2
- OR2T2 | c.321C>A p.T107= | Silent (SNP) | VAF 94/554 reads (17%) | catalogued as rs1553319728, COSV61618423, COSV61619116; called by muse, mutect2, varscan2
- PCDHGB5 | c.1887C>A p.G629= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV54019298; called by muse, mutect2, varscan2
- PKHD1L1 | c.5586A>C p.T1862= | Silent (SNP) | VAF 80/103 reads (78%) | catalogued as COSV101006764; called by muse, mutect2, varscan2
- PLEKHG3 | c.2595C>A p.R865= (on ENST00000394691; = p.R921= on NM_001308147.2) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99907071; called by muse, mutect2, varscan2
- POTED | c.147C>T p.H49= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1268961181, COSV55049596; called by muse, mutect2, varscan2
- POU3F4 | c.219C>T p.T73= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100937324; called by muse, mutect2
- PRAMEF4 | c.981C>A p.T327= | Silent (SNP) | VAF 61/182 reads (34%) | catalogued as COSV99339392; called by mutect2, varscan2
- PRICKLE3 | c.246C>T p.S82= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99603074; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1155G>A p.T385= (on ENST00000352766; = p.T306= on NM_181334.5) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs773455283, COSV100424642; called by muse, mutect2, varscan2
- SALL1 | c.675C>T p.A225= | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as rs144398338; called by muse, mutect2, varscan2
- SLC12A3 | c.1362G>A p.A454= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs372425406; ClinVar: likely benign; called by muse, mutect2, varscan2
- SOHLH1 | c.312C>T p.A104= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs777863724, COSV100040472; called by muse, mutect2, varscan2
- STAT4 | c.993G>T p.P331= | Silent (SNP) | VAF 81/455 reads (18%) | catalogued as COSV100636189, COSV61832397; called by muse, mutect2, varscan2
- SYNE1 | c.13383A>T p.A4461= (on ENST00000367255 / NM_182961.4; = p.A4390= on NM_033071.3) | Silent (SNP) | VAF 48/63 reads (76%) | catalogued as COSV99577023; called by muse, mutect2, varscan2
- TAS2R30 | c.6A>C p.I2= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101115547; called by muse, mutect2
- TG | c.2640G>T p.P880= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99602982; called by muse, mutect2, varscan2
- THOC5 | c.594G>T p.R198= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100803653; called by muse, mutect2, varscan2
- TNN | c.1851G>A p.P617= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs751058824, COSV53427997; called by muse, mutect2, varscan2
- TRPC6 | c.1026C>T p.V342= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs765798444, COSV100723752; called by muse, mutect2, varscan2
- WIPF1 | c.930G>C p.P310= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99769367; called by muse, mutect2, varscan2
- ZBTB26 | c.1230G>T p.G410= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV101021155, COSV65403789; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826705 G>T | 3'Flank (SNP) | VAF 93/247 reads (38%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502574 G>A | 5'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- DNM1P46 | n.1076G>C | RNA (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- GRIA4 | c.2295-5927G>A | Intron (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99234248; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85689G>A | Intron (SNP) | VAF 81/167 reads (49%) | catalogued as rs755203559; called by muse, mutect2, varscan2
- MTMR1 | c.1656+218G>C | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100953154; called by mutect2, varscan2
- NXF5 | n.1303C>A | RNA (SNP) | VAF 105/257 reads (41%) | catalogued as COSV99534635; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792033 C>T | 3'Flank (SNP) | VAF 20/46 reads (43%) | catalogued as rs375758732; called by muse, mutect2, varscan2
- SSPOP | n.12155C>A | RNA (SNP) | VAF 24/48 reads (50%) | catalogued as rs748003899, COSV100947983, COSV65130945; called by muse, mutect2, varscan2
